Somatic mutation profile of tumor specimen TCGA-A5-A0RA-01A (aliquot TCGA-A5-A0RA-01A-21D-A10B-09) from TCGA case TCGA-A5-A0RA, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 68.6 years (25,060 days).
Specimen TCGA-A5-A0RA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79be168b-75a7-467e-aaaa-d403c9537ca6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A5-A0RA-10A (Blood Derived Normal), aliquot TCGA-A5-A0RA-10A-01D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b670a9a-7321-47fb-af3d-b0ce90e702f1

The open-access MAF lists 82 somatic variants for this specimen: 70 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 11, Frame Shift Del 4, In Frame Del 2, Frame Shift Ins 2, Nonsense Mutation 2, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.30_53del p.W11_P18del | In Frame Del (DEL) | VAF 14/49 reads (29%) | hotspot (GDC flag); catalogued as COSV55995640; called by mutect2, pindel, varscan2
- PIK3CA | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.177); catalogued as rs200018596, CM1312620, COSV55890007, COSV55898949, COSV55991501; called by muse, mutect2, varscan2
- PTEN | c.209+4_209+7del p.X70_splice | Splice Site (DEL) | VAF 16/69 reads (23%) | hotspot (GDC flag); catalogued as rs398123318; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 67/220 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AP1M1 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52229136; called by muse, mutect2, varscan2
- ARHGAP27 | c.1784A>G p.D595G (on ENST00000428638 / NM_001282290.1; = p.D254G on NM_199282.3) | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV65358787; called by muse, mutect2, varscan2
- ARID5B | c.1282del p.S428Vfs*51 | Frame Shift Del (DEL) | VAF 32/107 reads (30%) | catalogued as COSV54429718; called by mutect2, pindel, varscan2
- ARMT1 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 64/222 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.302); catalogued as rs200751030, COSV66179096; called by muse, mutect2, varscan2
- ATP7B | c.2198T>G p.I733S | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54444289; called by muse, mutect2, varscan2
- BCORL1 | c.663C>G p.F221L | Missense Mutation (SNP) | VAF 64/199 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV54406834; called by muse, mutect2, varscan2
- BEND2 | c.1983C>A p.S661R | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV66217275; called by muse, mutect2, varscan2
- BEST1 | c.1250G>A p.R417K | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56446605; called by muse, mutect2, varscan2
- CAVIN1 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.073); catalogued as rs61729284, COSV63812783; called by muse, mutect2, varscan2
- CCPG1 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 85/301 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs745580071, COSV51243940; called by muse, mutect2, varscan2
- CD101 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56721172; called by muse, mutect2, varscan2
- CETN1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as rs1381045445, COSV59120983; called by muse, mutect2, varscan2
- CLEC4A | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 78/258 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.036); catalogued as rs200191238, COSV57562797; called by muse, mutect2, varscan2
- CXADR | c.1070C>G p.A357G | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53031269; called by muse, mutect2, varscan2
- CYSLTR2 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs148425155; called by muse, mutect2, varscan2
- DNAH7 | c.6616del p.R2206Vfs*32 | Frame Shift Del (DEL) | VAF 29/168 reads (17%) | catalogued as COSV56786144; called by mutect2, pindel, varscan2
- DOCK2 | c.5303T>C p.V1768A | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.02); catalogued as COSV56987813; called by muse, mutect2, varscan2
- DSG1 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57133188; called by muse, mutect2, varscan2
- EPHA3 | c.1616G>A p.S539N | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs964408959, COSV60727177; called by muse, mutect2, varscan2
- FGD6 | c.2627C>T p.A876V | Missense Mutation (SNP) | VAF 105/361 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV59697126; called by muse, mutect2, varscan2
- GAS6 | c.1261C>A p.L421M | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV59855768; called by muse, mutect2, varscan2
- GLRA4 | c.822G>C p.W274C | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65456969; called by muse, mutect2, varscan2
- GPR179 | c.6791G>A p.R2264Q (on ENST00000621958; = p.R2263Q on NM_001004334.4) | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs376816096; called by muse, mutect2, varscan2
- GRIN2B | c.2130C>G p.N710K | Missense Mutation (SNP) | VAF 91/333 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV74207840; called by muse, mutect2, varscan2
- HPS1 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV57270381; called by muse, mutect2, varscan2
- IGF2BP1 | c.248T>C p.I83T | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV51735961; called by muse, mutect2, varscan2
- IL2RA | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 68/239 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs886047083, COSV56923028, COSV99906860; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IREB2 | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs753403583, COSV51922325; called by muse, mutect2, varscan2
- KAT8 | c.507G>T p.E169D | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54897608; called by muse, mutect2, varscan2
- KLHDC4 | c.1251C>A p.D417E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs1223546265, COSV54511262; called by muse, mutect2
- LPGAT1 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65352083; called by muse, mutect2, varscan2
- LZTR1 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 79/237 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs886041418, COSV53146443, COSV53148082; called by muse, mutect2, varscan2
- MSL1 | c.1511C>T p.S504L (on ENST00000398532 / NM_001365919.1; = p.S241L on NM_001012241.2) | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.02); catalogued as rs1169850103, COSV59898970; called by muse, mutect2, varscan2
- NAA30 | c.953T>C p.V318A | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV53648720; called by muse, mutect2, varscan2
- NACC1 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs777031740, COSV52835995; called by muse, mutect2, varscan2
- NBEA | c.8206del p.D2736Tfs*25 | Frame Shift Del (DEL) | VAF 55/274 reads (20%) | catalogued as COSV59822403; called by pindel, varscan2*
- NPHP4 | c.64C>T p.R22C | Missense Mutation (SNP) | VAF 52/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773309269, COSV65397986; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NR2E3 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as rs374483122; called by muse, mutect2, varscan2
- NRXN1 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 85/286 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372823663; called by muse, mutect2, varscan2
- PCDHA8 | c.1730C>T p.A577V | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs781959729, COSV65323849; called by muse, mutect2
- PIKFYVE | c.1237A>G p.M413V | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs1416218682, COSV52249006; called by muse, mutect2, varscan2
- PPP1R3A | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs756250126, COSV52878213, COSV52879159, COSV99493264; called by muse, mutect2, varscan2
- PRPF8 | c.4774G>T p.D1592Y | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59260109, COSV59267815; called by muse, mutect2, varscan2
- PSG1 | c.657A>G p.I219M | Missense Mutation (SNP) | VAF 69/281 reads (25%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.705); catalogued as COSV54957206; called by muse, mutect2, varscan2
- RAD51AP2 | c.2039C>T p.P680L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs187028078, COSV67589086; called by muse, mutect2, varscan2
- RIMS1 | c.2327G>A p.R776H | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs551537892, COSV53484559; called by muse, mutect2, varscan2
- RNF41 | c.182C>G p.T61R | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.596); catalogued as COSV61505173; called by muse, mutect2, varscan2
- SERPINA7 | c.139G>T p.A47S | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.917); catalogued as COSV59667349; called by muse, mutect2
- SLC19A3 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs542566978, COSV51454877; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMCO4 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 61/270 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs140592708, COSV100127888, COSV54360616; called by muse, mutect2, varscan2
- SPOP | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as COSV61654573; called by muse, mutect2, varscan2
- SPTB | c.6208A>G p.K2070E | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV61552636; called by muse, mutect2, varscan2
- SSTR1 | c.614C>A p.T205K | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.069); catalogued as COSV57457715; called by muse, mutect2, varscan2
- STAG2 | c.1768C>T p.Q590* | Nonsense Mutation (SNP) | VAF 56/175 reads (32%) | catalogued as COSV54372356; called by muse, mutect2, varscan2
- THSD7A | c.2245C>A p.P749T | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.119); catalogued as COSV70272679; called by muse, mutect2, varscan2
- TNRC6C | c.2944G>A p.V982M | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0.007); catalogued as rs1212900362, COSV56940092; called by muse, mutect2, varscan2
- UBE2E1 | c.359A>G p.Y120C | Missense Mutation (SNP) | VAF 97/305 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60669778; called by muse, mutect2, varscan2
- UTRN | c.8191C>A p.H2731N | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.094); catalogued as rs1304268276, COSV62312786; called by muse, mutect2, varscan2
- WDR81 | c.5504A>G p.K1835R (on ENST00000409644 / NM_001163809.2; = p.K784R on NM_152348.4) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV58488323; called by muse, mutect2, varscan2
- ZNF419 | c.1504C>T p.R502* | Nonsense Mutation (SNP) | VAF 48/118 reads (41%) | catalogued as rs780492256, COSV55657663; called by muse, mutect2, varscan2
- ZNF423 | c.1043G>T p.C348F (on ENST00000563137 / NM_001379286.1; = p.C340F on NM_015069.4) | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.567); catalogued as COSV52204519; called by muse, mutect2, varscan2
- ZNF480 | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57998348; called by muse, mutect2, varscan2
- CMTM1 | c.191_192del p.Y64Cfs*17 (on ENST00000457188 / NM_181269.3; = p.Y181Cfs*17 on NM_052999.4) | Frame Shift Del (DEL) | VAF 66/258 reads (26%) | called by pindel, varscan2
- MAP3K1 | c.1428dup p.E477Rfs*4 | Frame Shift Ins (INS) | VAF 32/104 reads (31%) | called by mutect2, pindel, varscan2
- PHF6 | c.789dup p.D264* (on ENST00000332070 / NM_032458.3; = p.D265* on NM_032335.3) | Frame Shift Ins (INS) | VAF 26/113 reads (23%) | called by mutect2, pindel, varscan2
- SAMHD1 | c.683_685del p.E228del | In Frame Del (DEL) | VAF 24/106 reads (23%) | called by mutect2, pindel, varscan2
- ARAF | c.1167C>T p.S389= | Silent (SNP) | VAF 27/82 reads (33%) | catalogued as COSV51695301; called by muse, mutect2, varscan2
- CADPS2 | c.1066C>T p.L356= | Silent (SNP) | VAF 41/127 reads (32%) | catalogued as COSV57357507; called by muse, mutect2, varscan2
- EFTUD2 | c.1047C>T p.F349= | Silent (SNP) | VAF 14/178 reads (8%) | catalogued as COSV68184857; called by muse, mutect2
- GABRB2 | c.345C>A p.L115= | Silent (SNP) | VAF 8/168 reads (5%) | catalogued as COSV50947108; called by muse, mutect2
- GOLGA6L9 | c.645G>A p.L215= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs75114238; called by muse, varscan2
- ITGAX | c.3054C>T p.P1018= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs151025403, COSV99191582; called by muse, mutect2, varscan2
- LRP1 | c.8292C>T p.D2764= | Silent (SNP) | VAF 40/118 reads (34%) | catalogued as rs200835075, COSV54504249; called by muse, mutect2, varscan2
- MYH11 | c.1833C>T p.S611= | Silent (SNP) | VAF 85/255 reads (33%) | catalogued as rs990109247, COSV55569605; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTK2B | c.2436G>A p.Q812= | Silent (SNP) | VAF 41/155 reads (26%) | catalogued as COSV57766073; called by muse, mutect2, varscan2
- RNF43 | c.648G>A p.S216= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as rs370069540; called by muse, mutect2, varscan2
- RPS19 | c.405C>G p.A135= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as COSV55744040; called by muse, mutect2, varscan2
- SMIM29 | c.*208C>G | 3'UTR (SNP) | VAF 15/60 reads (25%) | catalogued as COSV58988957; called by muse, mutect2, varscan2
